Gene-level copy-number profile of tumor specimen C3L-08241-01 from CPTAC case C3L-08241, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.3 years (24,946 days).
Specimen C3L-08241-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6ac734b4-a6e0-441d-bd29-4862a52f5d27.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08241-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/61c4c25e-0138-41eb-97e2-11c1c3a2e30e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 4,139; copy number 2: 43,076; copy number 3: 9,312; copy number 4: 1,711; copy number 5: 93; copy number 30: 2; copy number 132: 3; copy number 194: 1; copy number 254: 2.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,611,440–130,718,831, 6 genes: POTEJ, RNU6-848P, CYP4F30P, AC140481.3, FAR2P3, KLF2P3.
- chr5:60,429,903–60,702,010, 9 genes (within-gene range 0–3): AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1.
- chr5:138,610,967–138,935,034, 5 genes (within-gene range 0–1): CTNNA1, AC113340.1, AC113340.2, AC034243.1, LRRTM2.
- chr5:139,012,329–139,012,441, 1 gene (within-gene range 0–1): RNA5SP194.
- chr5:163,796,065–166,155,439, 17 genes: RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1.
- chr7:110,724,159–110,725,825, 1 gene (within-gene range 0–2): AC073326.1.
- chr17:4,269,259–4,366,628, 3 genes (within-gene range 0–1): UBE2G1, MFSD1P1, RN7SL774P.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–1): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:11,618,208–11,644,824, 4 genes: AP001120.4, NPIPB1P, AP001120.2, AP001120.3.
- chr18:39,676,721–39,676,779, 1 gene (within-gene range 0–1): MIR5583-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,654,890–87,655,243, 1 gene, copy number 5: RPS14P5.
- chr3:195,836,193–198,123,232, 92 genes, copy number 5 (broad region; genes not listed).
- chr17:39,671,122–39,730,532, 4 genes, copy number 30–254: PGAP3, ERBB2, MIR4728, MIEN1.
- chr17:65,635,537–66,192,133, 1 gene, copy number 194 (within-gene range 2–194): CEP112.
- chr17:66,197,693–66,267,848, 3 genes, copy number 132: PSMD7P1, APOH, RNA5SP444.

Autosomal genes at a single copy (total copy number 1): 4,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
